Gene-level copy-number profile of tumor specimen TCGA-43-6770-01A from TCGA case TCGA-43-6770, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 59.4 years (21,683 days).
Specimen TCGA-43-6770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.17990372-154e-4933-99da-cc4f2ffdbc61.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-6770-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/92f1cdf6-bc4e-46e8-8822-1232b825b619

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 15,646; copy number 2: 33,938; copy number 3: 7,339; copy number 4: 1,794; copy number 5: 682; copy number 6: 26; copy number 7: 343; copy number 8: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-6770-01A-11D-1816-01): tumor purity 0.69, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:11,275,314–13,836,571, 20 genes (within-gene range 0–1): AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr10:86,749,754–87,024,732, 15 genes (within-gene range 0–1): AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 924 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,569,693–193,176,864, 448 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:195,544,048–198,222,513, 112 genes, copy number 5 (broad region; genes not listed).
- chr5:7,830,378–32,444,740, 338 genes, copy number 5 (broad region; genes not listed).
- chr22:46,576,012–48,850,912, 26 genes, copy number 6 (within-gene range 4–6): GRAMD4, CERK, AL118516.1, TBC1D22A, TBC1D22A-AS1, FP325331.1, Z83836.1, Z82186.1, LINC01644, LINC00898, AL117329.1, AL117329.2, FP325330.3, FP325330.1, FP325330.2, BX284656.2, BX284656.1, AL008720.1, MIR3201, AL008720.2, Z72006.1, Z82249.1, Z84468.2, TAFA5, Z84468.1, MIR4535.

Autosomal genes at a single copy (total copy number 1): 15,616. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
